Somatic mutation profile of tumor specimen C3L-04479-01 (aliquot CPT0238920007) from CPTAC case C3L-04479, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 66.3 years (24,207 days).
Specimen C3L-04479-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdbe0edc-a86f-4a7c-8c76-6fe6d001ad39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04479-31 (Blood Derived Normal), aliquot CPT0238950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb40a086-f22e-4170-9edc-c8a6a8357308

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 2, In Frame Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 114/703 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 48/632 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- CACNA1A | c.4922T>C p.V1641A | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64200153; called by muse, mutect2
- IL1RAPL2 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as rs1356086837, COSV61143550; called by muse, mutect2, varscan2
- MS4A7 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 50/628 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV100279656; called by muse, mutect2
- MYO15A | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs372516960; called by muse, mutect2
- NOTUM | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs780508873, COSV68826063; called by muse, mutect2, varscan2
- OR2T1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV63542812; called by muse, mutect2
- PCDHGA4 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 53/583 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs762398968, COSV53893624; called by muse, mutect2
- PTPRT | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 58/666 reads (9%) | catalogued as COSV61958074; called by muse, mutect2
- CPA1 | c.589_591dup p.T197dup | In Frame Ins (INS) | VAF 29/240 reads (12%) | called by mutect2, pindel, varscan2
- DOCK7 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 23/274 reads (8%) | called by muse, mutect2
- MFSD6 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 49/532 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- NFATC3 | c.2657G>A p.C886Y | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OSBP2 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- RNH1 | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 42/553 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- STIP1 | c.1262T>C p.I421T | Missense Mutation (SNP) | VAF 56/664 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- TCAP | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TLE2 | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.344); called by muse, mutect2
- ADGRG4 | c.6813G>A p.T2271= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs375322857, COSV54948883; called by muse, mutect2, varscan2
- BCR | c.360G>A p.E120= | Silent (SNP) | VAF 37/305 reads (12%) | called by muse, mutect2, varscan2
- GPRIN1 | c.2898C>A p.G966= | Silent (SNP) | VAF 7/67 reads (10%) | called by mutect2, varscan2
- POC1B-GALNT4 | c.66C>A p.T22= | Silent (SNP) | VAF 33/449 reads (7%) | called by muse, mutect2
- PTPRT | c.1839C>T p.P613= | Silent (SNP) | VAF 53/379 reads (14%) | catalogued as rs757922932, COSV61988819; called by muse, mutect2, varscan2
- SLC1A6 | c.1290C>T p.Y430= | Silent (SNP) | VAF 55/532 reads (10%) | catalogued as rs1243687532; called by muse, mutect2, varscan2
- UBE3C | c.1851G>A p.T617= | Silent (SNP) | VAF 51/572 reads (9%) | catalogued as rs777222555; called by muse, mutect2
- ZNF562 | c.477A>G p.G159= (on ENST00000453372 / NM_001130032.2; = p.G87= on NM_017656.4) | Silent (SNP) | VAF 23/435 reads (5%) | called by muse, mutect2
- MIR377 | n.6C>A | RNA (SNP) | VAF 23/469 reads (5%) | called by muse, mutect2
- SPNS2 | c.1608-17G>A | Intron (SNP) | VAF 51/496 reads (10%) | catalogued as rs200081709; called by muse, mutect2, varscan2
